Somatic mutation profile of tumor specimen BA2661D (aliquot aq-BA2661D) from BEATAML1.0 case 2287, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.0 years (20,463 days).
Specimen BA2661D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fbf6451-48b9-45d0-819b-d357fb89ec63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2907D (Solid Tissue Normal), aliquot aq-BA2907D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/822313dc-efb5-40e8-aa5f-64e8a3bc6e7a

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Ins 3, Nonsense Mutation 2, 3'UTR 2, Intron 1, Splice Site 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2523C>A p.N841K | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs749281035, COSV54048539; ClinVar: likely pathogenic; called by muse, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 24/72 reads (33%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PMS2 | c.2006+1G>A p.X669_splice | Splice Site (SNP) | VAF 43/123 reads (35%) | catalogued as rs1554297040; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANXA11 | c.1458G>A p.S486= | Splice Region (SNP) | VAF 14/35 reads (40%) | catalogued as rs1209281718; called by muse, mutect2
- BAHCC1 | c.2550dup p.G851Rfs*223 | Frame Shift Ins (INS) | VAF 28/95 reads (29%) | catalogued as rs1555653824; called by mutect2, pindel, varscan2
- CFAP65 | c.4706C>T p.A1569V | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs539966943; called by muse, mutect2, varscan2
- DNMT3A | c.2147T>A p.V716D | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs778857953, COSV53048255; called by mutect2, varscan2
- FAM118B | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs773622705, COSV64156980; called by muse, mutect2, varscan2
- FAM160B2 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.786); catalogued as rs760902459; called by muse, varscan2
- MUC3A | c.7759G>A p.A2587T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.014); catalogued as rs1318279443; called by muse, varscan2
- PTPN14 | c.687T>G p.C229W | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1408890299; called by muse, mutect2, varscan2
- RAD21 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 36/231 reads (16%) | catalogued as COSV52064246; called by muse, mutect2, varscan2
- ADRA2C | c.1239G>T p.Q413H | Missense Mutation (SNP) | VAF 88/171 reads (51%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- CNTN3 | c.1275C>G p.S425R | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- DLGAP3 | c.995G>C p.W332S | Missense Mutation (SNP) | VAF 67/130 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HSH2D | c.575dup p.S194Ifs*108 | Frame Shift Ins (INS) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- MIPEP | c.1820T>A p.F607Y | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- MUC6 | c.6754_6765del p.P2252_T2255del | In Frame Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- PDGFB | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- WAC | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 73/228 reads (32%) | called by muse, mutect2, varscan2
- F12 | c.546G>T p.P182= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99499853; called by muse, mutect2
- OR2AG1 | c.480C>T p.T160= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs930003422, COSV56625836; called by muse, mutect2, varscan2
- PTGIS | c.975G>A p.S325= | Silent (SNP) | VAF 88/177 reads (50%) | catalogued as rs140787750, COSV54834984; called by muse, mutect2, varscan2
- RPS6KL1 | c.12G>T p.V4= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- FMO3 | c.133-2602C>T | Intron (SNP) | VAF 73/174 reads (42%) | called by muse, mutect2, varscan2
- MIEN1 | c.*3G>T | 3'UTR (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- SSTR5 | c.*11G>A | 3'UTR (SNP) | VAF 10/28 reads (36%) | catalogued as rs779808706; called by muse, varscan2
